CCDI case PBBYUE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/bc5d8ba2-3598-4b5d-a389-636308667340

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8010/6; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.7 years (5,376 days).

Biospecimens (3 samples)
- Sample 0DM4X1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM4XH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DM4XT: Tissue type: Tumor; Specimen type: Solid Tissue.
